Somatic mutation profile of tumor specimen ALCH-B28Q-TTP1-A (aliquot ALCH-B28Q-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B28Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 64.5 years (23,544 days).
Specimen ALCH-B28Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18b5fbeb-4f06-4e11-98a9-0c7e89504d8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28Q-NB1-A (Blood Derived Normal), aliquot ALCH-B28Q-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b35b260-356d-4fc9-899a-007fb9585da5

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.1976T>A p.V659D | Missense Mutation (SNP) | VAF 59/163 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99509015; called by muse, mutect2, varscan2
- C1GALT1 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1369858065; called by muse, mutect2
- DNMT3B | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52416944, COSV52421021; called by muse, mutect2
- GAL3ST2 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV51950437; called by muse, mutect2
- ITSN1 | c.2477A>G p.K826R | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as rs1351914489; called by muse, mutect2
- MAP4K4 | c.2886C>G p.I962M (on ENST00000347699 / NM_001242559.2; = p.I880M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56335617; called by muse, mutect2
- PDZRN4 | c.2878C>T p.R960C (on ENST00000402685 / NM_001164595.2; = p.R702C on NM_013377.4) | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54195537; called by muse, mutect2
- PRTG | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377115254; called by muse, mutect2
- ADGRG4 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2
- FAM171B | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- FRS2 | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 11/356 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- GLI2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB16 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); called by muse, mutect2
- MUC19 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- OBP2A | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.388); called by muse, mutect2
- OR2J1 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2
- PCMTD2 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNTNAP5 | c.3117C>T p.N1039= | Silent (SNP) | VAF 22/539 reads (4%) | catalogued as rs1310896364; called by muse, mutect2
- ERBB2 | c.1977T>A p.V659= | Silent (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- ITPR2 | c.2760C>T p.T920= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- MED15 | c.2346G>A p.Q782= (on ENST00000263205 / NM_001003891.3; = p.Q742= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- MYO18A | c.1575G>A p.K525= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs1470416799; called by mutect2, varscan2
- SLC9A6 | c.*48G>A | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
